Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YL, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YL-11A (Solid Tissue Normal).

[page 1 of 2]
Patient Name: [REDACTED] Accession #: [REDACTED]
Med Rec No: [REDACTED] Client: [REDACTED] Taken: [REDACTED]
DOB: [REDACTED] Location: [REDACTED] Received: [REDACTED]
Gender: F Pt. Phone no [REDACTED] Reported: [REDACTED]
Physician(s): [REDACTED]
cc: [REDACTED]

ICD - 0-3 not applicable.

Normal path from non-cancer patient.

mu n/a/u

Uterus, cervix, tubes and ovaries

Uterus, cervix, tubes and ovaries:

Cervix:	Focal residual severe glandular dysplasia, margins clear
Endometrium:	Atrophic
Myometrium:	Adenomyosis
Right ovary:	Benign serous inclusions
Right tube:	Unremarkable
Left ovary:	Benign serous inclusions
Left tube:	Unremarkable

Received: Uterus and cervix with bilateral adnexa in formalin
Labeled: "uterus, cervix and bso"
Weight: 61 gms
Size
Uterus: 6.0 cm from the tip of the cervix to the top of fundus x 4.5 cm across the fundus laterally and 2.3 cm from anterior to posterior
Right ovary: 3.0 x 0.6 x 0.7 cm
Left ovary: 3.1 x 1.2 x 0.6 cm
Appearance
Serosal surface: Normal
Tumor: Not grossly evident
Cervix: Is covered by smooth pink-tan mucosa with irregular dark tan areas consistent with previous biopsy
Endometrium: Smooth and pink tan, pale tan 0.5 cm in greatest diameter, slightly raised area along the lower part of the posterior wall of the fundus
Right tube and ovary: Right tube has been previously sectioned and measures 1.5 cm in length proximal to the section and 2.0 cm in length distally. Appears otherwise normal. The right ovary is a 1.5 x 0.6 cm portion previously removed and otherwise appears normal.

Regulatory System:

The following information may be applicable to some of the respondents listed in the above report and is being provided for your information and use.

Some studies are supported by the U.S. Food and Drug Administration. The FDA in 1986 announced that there was no evidence to support the use of marijuana. This has caused for various purposes, it is important. The laboratory is needed under the Federal Laboratory Inspection Amendments of 1980 (FLIA) required to maintain high quality. Some other study during

[page 2 of 2]
[REDACTED]

Surgical Pathology Report

[REDACTED]

Left tube and ovary: Left tube has been previously sectioned measures 3.0 cm in length proximal to the section and 1.0 cm in length distal. The left ovary is 0.9 x 0.4 cm portion previously removed and cut surface otherwise is unremarkable.

Lymph nodes: None grossly evident

Representative sections are submitted.

Key to cassettes:

- | | | |
|---|---|--|
| 1 | - | Full thickness cervix from 12 o'clock to 3 o'clock |
| 2 | - | Cervix 3 o'clock to 6 o'clock |
| 3 | - | Cervix 6 o'clock to 9 o'clock |
| 4 | - | Cervix 9 o'clock to 12 o'clock |
| 5 | - | Posterior wall of the uterus including endometrium/myometrium and serosa |
| 6 | - | Right ovary and fallopian tube |
| 7 | - | Left ovary and fallopian tube |

Microscopic Description

The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file 2ce0e746-4811-4f2c-b9a5-c6b610936a0b (TCGA-FL-A1YL.5C686996-6F26-4A31-B53E-AC9561DAC9FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).